Somatic mutation profile of tumor specimen 0DA8M9 from CCDI case PBBJVW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Myxopapillary ependymoma; Tissue or organ of origin: Spinal cord; Age at diagnosis: 15.9 years (5,812 days).
Specimen 0DA8M9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4fb72449-0352-49a7-bb46-8c012c62f83f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DA8L9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0e1c7696-6bf1-4553-967b-b6e10c804485

The open-access MAF lists 4 somatic variants for this specimen: 1 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 2, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RIBC1 | c.915_916del p.L306Gfs*3 | Frame Shift Del (DEL) | VAF 285/489 reads (58%) | called by pindel, varscan2
- C11orf21 | c.54-145C>T | Intron (SNP) | VAF 26/494 reads (5%) | catalogued as rs1417649641, COSV51722127; called by muse, mutect2
- NXF1 | c.1822-28A>G | Intron (SNP) | VAF 197/284 reads (69%) | catalogued as rs748430818; called by muse, mutect2, varscan2
- RPLP1 | c.-97C>G | 5'UTR (SNP) | VAF 16/37 reads (43%) | catalogued as rs903166721, COSV52979077; called by muse, mutect2, varscan2
